Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3549, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3549-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with an ulcerated colon carcinoma of histological type of a moderately differentiated colorectal adenocarcinoma, measuring 3.5 cm in diameter at the widest point, located in the passage from the cecum to the ascending colon. Invasive spreading of the tumor to the muscularis propria.

Colonic mucous membrane with a small solitary tubular adenoma with moderate epithelial dysplasia (synonymously: mild intraepithelial neoplasia).

A coarse, nodular calcified focus of the mesenterium. It is most likely a completely calcified lymph node.

Oral and aboral resection margin is tumor-free.

31 regular lymph nodes are tumor-free with uncharacteristically reactive changes.

Tumor stage therefore pT2 nN0 (0/31) V0 L0; G2 R0.

Source: NCI Genomic Data Commons file 472611ef-890a-4f45-a5d8-25a790246e4a (TCGA-AA-3549.C241ECE3-8A28-4984-AEA5-CBB5379E8D75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).